CCDI case PBCCGJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/e97a1459-03e4-462b-95c3-ccad41800130

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Papillary carcinoma, NOS: ICD-O-3 morphology code: 8050/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 16.2 years (5,927 days).

Biospecimens (3 samples)
- Sample 0DOQG5: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DOQGJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DOQGN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
